Somatic mutation profile of tumor specimen C3N-03070-02 (aliquot CPT0208980006) from CPTAC case C3N-03070, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.0 years (24,111 days).
Specimen C3N-03070-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8be75ee-d983-438d-b2ac-4a047b8db78d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03070-31 (Blood Derived Normal), aliquot CPT0209010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b827d512-5b71-4f76-b7a9-9e67df3a2edc

The open-access MAF lists 97 somatic variants for this specimen: 67 protein-altering or splice-affecting, 21 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 21, RNA 3, Nonsense Mutation 2, Splice Site 2, 5'Flank 2, 3'UTR 2, Intron 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 57/151 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 445/485 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 54/464 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs377676303; called by muse, mutect2, varscan2
- CATSPER1 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 122/728 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs143644621; called by muse, mutect2, varscan2
- CCDC92 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs139365870, COSV99435417; called by muse, mutect2
- CCK | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 68/156 reads (44%) | catalogued as rs778151078, COSV58183411, COSV58183755; called by muse, mutect2, varscan2
- CFAP47 | c.5320+1del | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | catalogued as COSV100545798; called by mutect2, varscan2
- CLASRP | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 34/622 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1215731788; called by muse, mutect2
- COQ4 | c.271_273del p.R91del | In Frame Del (DEL) | VAF 48/168 reads (29%) | catalogued as rs762561620; called by pindel, varscan2
- ESPNL | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 36/415 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1458652568; called by muse, mutect2
- EXT1 | c.542T>A p.L181H | Missense Mutation (SNP) | VAF 124/515 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV65483886; called by muse, mutect2, varscan2
- FGF11 | c.553A>G p.N185D | Missense Mutation (SNP) | VAF 45/624 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1477081619; called by muse, mutect2
- FLG | c.3151C>T p.R1051C | Missense Mutation (SNP) | VAF 146/606 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs201961522, COSV64237239; called by muse, mutect2, varscan2
- FNDC1 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51932954; called by muse, varscan2
- FRY | c.6791A>G p.N2264S | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs1203033337; called by muse, mutect2, varscan2
- GOLGB1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762516224, COSV100510237; called by muse, mutect2
- GSTK1 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs140903213; called by muse, mutect2, varscan2
- GUCA2B | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs140898399; called by muse, mutect2, varscan2
- HUWE1 | c.12134G>A p.R4045Q | Missense Mutation (SNP) | VAF 45/585 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV53350108; called by muse, mutect2
- KLF11 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 97/390 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370291287; called by muse, mutect2, varscan2
- MAP3K15 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs781456790; called by muse, mutect2, varscan2
- MS4A14 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 84/305 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs762035217, COSV55733751; called by muse, mutect2, varscan2
- OR5T2 | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs140494820; called by muse, mutect2, varscan2
- P3H2 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as rs1251221204; called by muse, mutect2, varscan2
- PAK1 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 18/224 reads (8%) | catalogued as rs769471788, COSV53702017; called by muse, mutect2
- PCDH15 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100228142; called by muse, mutect2, varscan2
- PEF1 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 46/622 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1313849281, COSV101035821; called by muse, mutect2
- PPFIA2 | c.3085C>A p.L1029I | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV61032847; called by muse, mutect2, varscan2
- RAPGEF3 | c.997C>G p.H333D (on ENST00000389212; = p.H291D on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 2452/2799 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs1239555937; called by muse, mutect2, varscan2
- ROS1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs376101389, COSV63853009; called by muse, mutect2, varscan2
- SYNM | c.2836C>T p.R946W | Missense Mutation (SNP) | VAF 238/571 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs5030694, COSV60374570; called by muse, mutect2, varscan2
- ZBTB47 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs758866637, COSV51765361; called by muse, mutect2, varscan2
- ACE2 | c.440-1G>A p.X147_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2
- ADGRG4 | c.1810A>T p.T604S | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AR | c.1525G>C p.V509L | Missense Mutation (SNP) | VAF 25/395 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.098); called by muse, mutect2
- CCDC59 | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CCNQ | c.565C>A p.Q189K | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2
- CHN1 | c.1042A>G p.R348G | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CLEC4E | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSF3R | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 142/335 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTR9 | c.2054T>C p.L685P | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DLGAP2 | c.3160C>G p.R1054G | Missense Mutation (SNP) | VAF 101/259 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DNAJB8 | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNAJC14 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- FCGR3A | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 127/560 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, varscan2
- FNDC1 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, varscan2
- FOXP3 | c.770A>T p.Q257L | Missense Mutation (SNP) | VAF 96/467 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FSIP2 | c.19023G>C p.L6341F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- HMCN1 | c.3556C>G p.Q1186E | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- KIAA1143 | c.109-2A>C p.X37_splice | Splice Site (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2
- KLHL13 | c.1009T>C p.S337P | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LAMA5 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 124/271 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR12 | c.1766A>G p.N589S | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.468); called by muse, mutect2
- MYH4 | c.3599A>C p.H1200P | Missense Mutation (SNP) | VAF 92/286 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- OR2T10 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- PDZD4 | c.722A>T p.E241V | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by mutect2, varscan2
- POTEF | c.383T>A p.F128Y | Missense Mutation (SNP) | VAF 182/525 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RALGAPB | c.32T>G p.V11G | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2
- ROCK1 | c.783G>T p.W261C | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SNX14 | c.1219G>C p.D407H (on ENST00000314673 / NM_001350535.1; = p.D363H on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX18 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STPG2 | c.881T>C p.F294S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2
- TAGLN2 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 86/473 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TMEM200C | c.1279G>A p.G427S | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2
- TTLL10 | c.547C>A p.H183N (on ENST00000379289 / NM_001130045.2; = p.H110N on NM_153254.3) | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- VEZT | c.1704C>A p.D568E | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZXDA | c.1941T>G p.N647K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by mutect2, varscan2
- ABCA12 | c.4002C>T p.N1334= (on ENST00000272895 / NM_173076.3; = p.N1016= on NM_015657.3) | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as COSV55952226; called by muse, mutect2
- ACTBL2 | c.456C>T p.I152= | Silent (SNP) | VAF 15/498 reads (3%) | catalogued as COSV70661035; called by muse, mutect2
- B3GALNT2 | c.435C>T p.V145= | Silent (SNP) | VAF 23/208 reads (11%) | called by muse, mutect2, varscan2
- CDC42BPB | c.1002G>A p.E334= | Silent (SNP) | VAF 89/382 reads (23%) | catalogued as rs1260785761, COSV63475265; called by muse, mutect2, varscan2
- CYB5D2 | c.468C>T p.T156= | Silent (SNP) | VAF 64/377 reads (17%) | called by muse, mutect2, varscan2
- DMRTA1 | c.1128A>G p.L376= | Silent (SNP) | VAF 40/276 reads (14%) | called by muse, mutect2, varscan2
- DTX3 | c.717C>T p.V239= | Silent (SNP) | VAF 166/6404 reads (3%) | called by muse, mutect2
- HCK | c.144T>C p.C48= | Silent (SNP) | VAF 88/216 reads (41%) | catalogued as rs1161918001; called by muse, mutect2, varscan2
- LRRC55 | c.705C>T p.G235= | Silent (SNP) | VAF 24/536 reads (4%) | catalogued as rs764183796, COSV73006510; called by muse, mutect2
- NIF3L1 | c.1116C>T p.D372= (on ENST00000409020 / NM_001369444.1; = p.D345= on NM_021824.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as rs1325582988; called by muse, mutect2, varscan2
- NSD1 | c.5415G>A p.L1805= | Silent (SNP) | VAF 64/204 reads (31%) | called by muse, mutect2, varscan2
- OTOGL | c.5325T>C p.Y1775= (on ENST00000547103; = p.Y1766= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- OTOP2 | c.1224G>T p.L408= | Silent (SNP) | VAF 34/628 reads (5%) | called by muse, mutect2
- PCDHA2 | c.2131T>C p.L711= | Silent (SNP) | VAF 25/632 reads (4%) | called by muse, mutect2
- RP1 | c.2271C>T p.F757= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs267601950, COSV55121104; called by muse, mutect2
- ST14 | c.1536C>T p.N512= | Silent (SNP) | VAF 107/602 reads (18%) | catalogued as rs138312612; called by muse, mutect2, varscan2
- TTC12 | c.1989C>T p.A663= | Silent (SNP) | VAF 20/364 reads (5%) | catalogued as rs145542172; called by muse, mutect2
- TTC16 | c.633C>T p.A211= | Silent (SNP) | VAF 50/238 reads (21%) | called by muse, mutect2, varscan2
- TTC22 | c.363G>C p.A121= | Silent (SNP) | VAF 36/741 reads (5%) | catalogued as rs778273387; called by muse, mutect2
- YWHAB | c.66T>C p.D22= | Silent (SNP) | VAF 28/130 reads (22%) | called by mutect2, varscan2
- ZNF318 | c.5472A>G p.K1824= | Silent (SNP) | VAF 25/167 reads (15%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*1121G>A | 3'UTR (SNP) | VAF 118/263 reads (45%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498455 T>G | 5'Flank (SNP) | VAF 33/291 reads (11%) | catalogued as rs1160303060; called by muse, mutect2, varscan2
- CDKN1B | c.*102C>T | 3'UTR (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- FHOD3 | c.1197-5182C>G | Intron (SNP) | VAF 24/160 reads (15%) | called by muse, mutect2
- GTF2IRD2P1 | n.1611G>C | RNA (SNP) | VAF 98/612 reads (16%) | called by muse, varscan2
- SCP2D1 | chr20:18809853 G>T | 5'Flank (SNP) | VAF 48/295 reads (16%) | called by mutect2, varscan2
- TTC19 | c.312+58C>T | Intron (SNP) | VAF 67/311 reads (22%) | called by muse, mutect2, varscan2
- U82695.1 | n.1765C>A | RNA (SNP) | VAF 146/467 reads (31%) | catalogued as rs1009004023; called by muse, mutect2, varscan2
- ZNF252P | n.2203T>A | RNA (SNP) | VAF 76/185 reads (41%) | called by muse, mutect2, varscan2
